Somatic mutation profile of tumor specimen 0E1AFO from CCDI case PBCVYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1AFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be081000-1dc5-40c0-a961-f7ca45b06a93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1AG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aa0a7a4-b138-4da8-9b17-671746ab838e

The open-access MAF lists 27 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, Intron 4, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF3C5 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 224/477 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762024144, COSV59601764; called by muse, mutect2, varscan2
- MUC17 | c.2178T>A p.S726R | Missense Mutation (SNP) | VAF 151/540 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV104402065; called by muse, mutect2, varscan2
- NBEA | c.6455T>C p.V2152A | Missense Mutation (SNP) | VAF 41/1051 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as rs1444472532; called by muse, mutect2
- PIK3AP1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs148582013; called by muse, mutect2, varscan2
- SEC24A | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 213/992 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV59745793; called by muse, mutect2, varscan2
- ABCA13 | c.6638T>G p.I2213S | Missense Mutation (SNP) | VAF 523/1089 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GPATCH8 | c.3907G>C p.A1303P | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, mutect2
- ILDR1 | c.659A>G p.H220R | Missense Mutation (SNP) | VAF 38/874 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- NDUFB1 | c.-5C>T | Splice Region (SNP) | VAF 94/411 reads (23%) | called by muse, mutect2, varscan2
- SPANXN2 | c.481T>G p.S161A | Missense Mutation (SNP) | VAF 132/340 reads (39%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.636); called by muse, varscan2
- TACR1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TARDBP | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 212/454 reads (47%) | called by muse, mutect2, varscan2
- WARS2 | c.325dup p.S109Kfs*11 | Frame Shift Ins (INS) | VAF 88/637 reads (14%) | called by mutect2, pindel, varscan2
- ABCC6 | c.2343G>A p.A781= | Silent (SNP) | VAF 101/413 reads (24%) | catalogued as rs768106519, COSV99228053; called by muse, mutect2, varscan2
- AJAP1 | c.675G>A p.T225= | Silent (SNP) | VAF 54/258 reads (21%) | catalogued as rs1459076033, COSV65450421; called by muse, mutect2, varscan2
- GASK1B | c.684G>A p.A228= | Silent (SNP) | VAF 120/470 reads (26%) | catalogued as rs373583614; called by muse, mutect2, varscan2
- HINFP | c.360C>T p.N120= | Silent (SNP) | VAF 112/399 reads (28%) | catalogued as rs369717979; called by muse, mutect2, varscan2
- RIPK2 | c.240A>C p.P80= | Silent (SNP) | VAF 185/988 reads (19%) | called by muse, mutect2, varscan2
- TAMALIN | c.975G>A p.R325= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- TMEM101 | c.375C>T p.S125= | Silent (SNP) | VAF 392/890 reads (44%) | catalogued as rs758413754; called by muse, mutect2, varscan2
- VANGL1 | c.681G>A p.V227= | Silent (SNP) | VAF 72/298 reads (24%) | catalogued as rs201698322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FEZ1 | c.939+39C>A | Intron (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- GABRG3 | c.270+66G>T | Intron (SNP) | VAF 19/568 reads (3%) | called by muse, mutect2
- NDUFA7 | c.102-9dup | Intron (INS) | VAF 38/297 reads (13%) | catalogued as rs1390249664; called by mutect2, pindel, varscan2
- PLXNC1 | c.-7del | 5'UTR (DEL) | VAF 16/92 reads (17%) | catalogued as rs1350913781; called by mutect2, pindel, varscan2
- PTPN14 | c.*43C>T | 3'UTR (SNP) | VAF 88/171 reads (51%) | catalogued as rs376531863; called by muse, mutect2, varscan2
- SUMF2 | c.397-59C>T | Intron (SNP) | VAF 8/126 reads (6%) | catalogued as rs1387608390, COSV51918986; called by muse, mutect2
